Somatic mutation profile of tumor specimen TCGA-38-4626-01A (aliquot TCGA-38-4626-01A-01D-1553-08) from TCGA case TCGA-38-4626, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 57.2 years (20,903 days).
Specimen TCGA-38-4626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df35c635-dd73-4f6f-b141-6000ce81cb49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4626-11A (Solid Tissue Normal), aliquot TCGA-38-4626-11A-01D-1553-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74d9e845-4334-4178-9da3-11b3c07a225d

The open-access MAF lists 223 somatic variants for this specimen: 172 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 47, Nonsense Mutation 10, Splice Site 4, Frame Shift Del 4, Intron 2, Splice Region 2, RNA 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55960455; called by muse, mutect2, varscan2
- ABLIM1 | c.1889G>T p.R630M | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV53313666; called by muse, mutect2
- ABRAXAS2 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV53718175; called by muse, mutect2, varscan2
- AC136428.1 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99067803; called by muse, mutect2
- ACYP2 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV100336707; called by muse, mutect2
- ADAMTS12 | c.4443C>A p.D1481E | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV61274723; called by muse, mutect2
- ADAMTS5 | c.1645C>A p.L549M | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV53180836; called by muse, mutect2
- ADGRE5 | c.916G>A p.D306N (on ENST00000242786 / NM_078481.4; = p.D213N on NM_001784.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV54414028; called by muse, mutect2
- AGMO | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61121541; called by mutect2, varscan2
- AHNAK2 | c.9384C>A p.D3128E | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs772058901, COSV60926642; called by muse, mutect2
- ALK | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101202284; called by muse, mutect2
- ANK2 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV52181922; called by muse, mutect2
- ANKRD34A | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1553761087, COSV60161805; called by muse, mutect2, varscan2
- ANTXR1 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.322); catalogued as COSV58019779; called by muse, mutect2
- APOB | c.10343C>A p.T3448N | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV51934923; called by muse, mutect2
- AQP10 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59248200; called by muse, mutect2, varscan2
- ATG4A | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100619781, COSV58966200; called by muse, mutect2
- ATP2B3 | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54856415, COSV54858080; called by muse, mutect2
- BCOR | c.2879C>A p.S960Y | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100653518; called by muse, mutect2, varscan2
- BMP7 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67782158; called by muse, mutect2
- BPIFB4 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100971561; called by muse, mutect2
- BUB1 | c.2895G>T p.K965N | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV57066271; called by muse, mutect2, varscan2
- CALML3 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100178837; called by muse, mutect2
- CAPRIN2 | c.1795G>T p.V599L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51834807; called by muse, mutect2
- CCDC148 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV99320776; called by muse, mutect2
- CCDC28A | c.22A>G p.R8G | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60425642; called by muse, mutect2, varscan2
- CEP170 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1443485710, COSV100317323; called by muse, mutect2
- CHST1 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.402); catalogued as rs747837712, COSV100346061, COSV57325116; called by muse, mutect2, varscan2
- CLEC1B | c.360C>A p.N120K | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53726412; called by muse, mutect2, varscan2
- CLEC6A | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.276); catalogued as COSV65988011; called by muse, mutect2, varscan2
- CYLC1 | c.847T>A p.Y283N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61415023; called by muse, mutect2
- DCDC1 | c.2299G>T p.A767S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV100663719; called by muse, mutect2
- DCTN1 | c.2886G>A p.K962= | Splice Region (SNP) | VAF 16/278 reads (6%) | catalogued as COSV62621262; called by muse, mutect2
- DDX60L | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52719906; called by muse, mutect2, varscan2
- DLG2 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV65864193; called by muse, mutect2
- DMD | c.5095G>A p.D1699N | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV63782150; called by muse, mutect2
- DPP10 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59714364; called by muse, mutect2
- DSC1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV57150175; called by muse, mutect2
- DUSP21 | c.114C>G p.N38K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.427); catalogued as COSV59134726; called by muse, mutect2
- DYNC1I1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 30/704 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV61468935; called by muse, mutect2
- E2F7 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59742691; called by muse, mutect2
- EBF2 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV68780025; called by muse, mutect2, varscan2
- EMILIN3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV60038250; called by muse, mutect2
- EPB41L3 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59464692; called by muse, mutect2
- ERCC6L2 | c.862A>T p.M288L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV56633594; called by muse, mutect2, varscan2
- FAM118B | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.956); catalogued as COSV64157558; called by muse, mutect2
- FAM169A | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV65847094; called by muse, mutect2
- FCRL4 | c.1087A>C p.N363H | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54865165; called by muse, mutect2
- FERD3L | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV51763973; called by muse, mutect2, varscan2
- FLNC | c.6274G>T p.E2092* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV57962434; called by muse, mutect2, varscan2
- GATAD2B | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64085632; called by muse, mutect2
- GIMAP8 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as rs1012337307, COSV100217588; called by muse, mutect2
- GJA10 | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65355962; called by muse, mutect2
- GLA | c.157A>T p.N53Y | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM124299, COSV54510325, COSV54510911; called by muse, mutect2
- GPC4 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63699370; called by muse, mutect2
- GPR174 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52131406, COSV99338212; called by muse, mutect2
- HDAC4 | c.3006A>T p.E1002D | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61873610; called by muse, mutect2
- HOXA2 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV56067464; called by muse, mutect2
- IGSF11 | c.705C>T p.P235= (on ENST00000393775 / NM_001015887.3; = p.P234= on NM_152538.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/242 reads (7%) | catalogued as COSV61176776; called by muse, mutect2
- IL1RAPL1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56290436; called by muse, mutect2
- KANSL1 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.294); catalogued as COSV52272789; called by muse, mutect2
- KCNJ16 | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV99388437; called by muse, mutect2
- KCNU1 | c.2428C>A p.Q810K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101299301; called by muse, mutect2, varscan2
- KLHL13 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53251854, COSV53253212; called by muse, mutect2
- KRTAP10-10 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV59975290; called by muse, mutect2, varscan2
- KRTAP26-1 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV100860438; called by muse, mutect2
- LAX1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV65849931; called by muse, mutect2
- LIPI | c.888T>A p.C296* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as COSV60715085; called by muse, mutect2, varscan2
- LRRIQ1 | c.2170A>T p.S724C | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV67836699; called by muse, mutect2
- MAGEA8 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1557371047, COSV54063910; called by muse, mutect2
- MAP3K4 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs747018394, COSV62337164, COSV62339611; called by muse, mutect2, varscan2
- MARCHF6 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV56885872; called by muse, mutect2, varscan2
- MGAM | c.3707C>T p.P1236L | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527706, COSV72075379; called by muse, mutect2
- MPZL1 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV63257156; called by muse, mutect2
- MRPL1 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 8/147 reads (5%) | catalogued as rs1341863396, COSV59676453; called by muse, mutect2
- MRPL35 | c.127A>C p.T43P | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99608052; called by muse, mutect2
- MUC16 | c.29147C>T p.T9716M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.67); catalogued as rs780444857, COSV67485584; called by mutect2, varscan2
- MUC16 | c.13608C>G p.N4536K | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs1434364716, COSV67485593; called by muse, mutect2
- MXRA5 | c.3487C>T p.R1163C | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780402358, COSV54246116; called by muse, mutect2
- MYBL2 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV99406498; called by muse, mutect2
- NAP1L4 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV65881887; called by muse, mutect2
- NCKAP5 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.587); catalogued as COSV58467323; called by muse, mutect2
- NIPBL | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56962054; called by muse, mutect2, varscan2
- NLRP12 | c.3031G>A p.G1011R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV60753029; called by muse, mutect2, varscan2
- NPR3 | c.1541G>T p.R514M (on ENST00000265074 / NM_001364458.2; = p.R513M on NM_000908.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1326193214, COSV54084231; called by muse, mutect2, varscan2
- OBI1 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV56144637, COSV56146823; called by muse, mutect2
- OR2L8 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 78/636 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100594364, COSV61727934; called by muse, mutect2, varscan2
- OR2T6 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as rs759247532, COSV63216901; called by muse, mutect2, varscan2
- OR4N5 | c.644T>A p.L215Q | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61321104; called by muse, mutect2, varscan2
- OR51F2 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59065797; called by muse, mutect2
- OR51L1 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100386439, COSV58625470; called by muse, mutect2
- OR5L1 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.483); catalogued as COSV61735071, COSV61735800; called by muse, mutect2, varscan2
- PCDH15 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs777620091, COSV57352925; called by muse, mutect2
- PCDHA11 | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.491); catalogued as rs781897836, COSV100250956, COSV56536338; called by muse, mutect2, varscan2
- PCDHA3 | c.1174C>A p.H392N | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as COSV63545023; called by muse, mutect2
- PCDHA9 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.168); catalogued as COSV65324257, COSV65328310; called by muse, mutect2
- PDE10A | c.1965C>A p.N655K | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV63103676; called by muse, mutect2
- PEAR1 | c.2679C>A p.S893R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52775223; called by muse, mutect2
- PLCB4 | c.2312G>T p.R771I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99595957; called by muse, varscan2
- PLEKHO1 | c.446A>C p.Y149S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV50311078; called by muse, mutect2, varscan2
- PLPP3 | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64840297; called by muse, mutect2
- PNLIPRP1 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 16/435 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV62613098; called by muse, mutect2
- POU6F2 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV101302597, COSV68880402; called by muse, varscan2
- PPEF2 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV54420334, COSV54425422; called by muse, mutect2, varscan2
- PPM1L | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV72263359; called by muse, mutect2, varscan2
- PPP2R1B | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59537218; called by muse, mutect2
- PRAMEF12 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.916); catalogued as COSV63216313; called by muse, mutect2
- PRAMEF20 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100326300; called by muse, mutect2
- PRPF8 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59266642; called by muse, mutect2
- PRR5L | c.1106G>T p.*369Lext*25 | Nonstop Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100287154; called by muse, mutect2
- PRSS58 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101616181, COSV73488799; called by muse, mutect2
- PSG6 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51834258; called by muse, mutect2
- PTCHD1 | c.2581A>T p.N861Y | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV101037808; called by muse, mutect2
- PTF1A | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV100919592; called by muse, mutect2
- PTPRT | c.2884+2T>A p.X962_splice | Splice Site (SNP) | VAF 18/232 reads (8%) | catalogued as COSV62010040; called by muse, mutect2
- RAD51AP1 | c.772G>T p.V258L (on ENST00000228843 / NM_001130862.2; = p.V241L on NM_006479.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV57410472; called by muse, mutect2, varscan2
- RAI14 | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV54289001, COSV54301469; called by muse, mutect2
- RANBP17 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV66655475; called by muse, mutect2, varscan2
- RERGL | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99967970; called by muse, mutect2
- RHOBTB1 | c.1845G>T p.W615C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100558477, COSV61959863; called by muse, mutect2
- ROR2 | c.2710G>T p.G904W | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.215); catalogued as COSV65222562; called by muse, mutect2
- RPGR | c.2795C>G p.S932* (on ENST00000339363 / NM_001367249.1; = p.S727* on NM_000328.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV58838939; called by muse, mutect2
- RTL3 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV58185430; called by muse, mutect2
- SAG | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs755757588, COSV68592092; called by muse, mutect2
- SAMD9 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 20/232 reads (9%) | catalogued as COSV66077135; called by muse, mutect2
- SATL1 | c.267G>T p.M89I (on ENST00000395409; = p.M276I on NM_001012980.2) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60578068; called by muse, mutect2
- SDCCAG8 | c.1722G>T p.M574I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100654592, COSV59415446; called by muse, mutect2
- SEC24A | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); catalogued as rs375080345; called by muse, mutect2, varscan2
- SERPINB13 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54030477; called by muse, mutect2
- SF3A3 | c.1281+1G>T p.X427_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | catalogued as COSV65956665; called by muse, mutect2
- SGPL1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV54737590; called by muse, mutect2
- SLC30A10 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100751537; called by muse, mutect2, varscan2
- SLC30A10 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 19/151 reads (13%) | catalogued as COSV63075327; called by muse, mutect2, varscan2
- SLC9B1 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV56474297, COSV56475750; called by mutect2, varscan2
- SLITRK4 | c.1584G>T p.L528F | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62024211, COSV62025711; called by muse, mutect2
- SNTG2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV58001026; called by muse, mutect2
- SOX7 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58731475; called by muse, mutect2, varscan2
- SPHKAP | c.3091G>T p.V1031F | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60890903; called by muse, mutect2
- STK32C | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV53844638; called by muse, mutect2, varscan2
- STRN | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55751245; called by muse, mutect2
- TARBP1 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 25/201 reads (12%) | catalogued as COSV50199838; called by muse, mutect2, varscan2
- TARS1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV99466105; called by muse, mutect2, varscan2
- TCF25 | c.1222-1G>T p.X408_splice | Splice Site (SNP) | VAF 8/138 reads (6%) | catalogued as COSV54531918; called by muse, mutect2
- TJP1 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62045274; called by muse, mutect2
- TKTL1 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV54214454; called by muse, mutect2
- TLR4 | c.1244G>T p.S415I (on ENST00000355622 / NM_138554.5; = p.S375I on NM_003266.4) | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV62924029; called by muse, mutect2
- TMEM144 | c.843T>G p.C281W | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV56702470; called by muse, mutect2
- TRIM51 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.314); catalogued as rs148245438, COSV55266044; called by muse, mutect2
- TRPV2 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58429791; called by muse, mutect2
- TRPV6 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63892957; called by muse, mutect2, varscan2
- USP34 | c.5973A>T p.E1991D | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV68404997; called by muse, mutect2
- USP34 | c.2589G>C p.L863F | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68405002; called by muse, mutect2
- WIPF2 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV60275354; called by muse, mutect2
- XPNPEP2 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941423, COSV64369998; called by muse, mutect2
- ZDHHC9 | c.23A>T p.K8M | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV64097232; called by muse, mutect2
- ZHX1 | c.1571G>T p.S524I | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV52878362; called by muse, mutect2
- ZNF23 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV61841558; called by muse, mutect2
- ZNF479 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58642561; called by muse, mutect2, varscan2
- ZNF804A | c.3105G>T p.L1035F | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56462836, COSV56465942; called by muse, mutect2
- ZNF99 | c.2263C>G p.H755D | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101233967, COSV68056421, COSV68056732; called by muse, mutect2
- EML3 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IGHV2-26 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV6-21 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by mutect2, varscan2
- MAGEB6B | c.278G>C p.S93T | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, mutect2
- MYH15 | c.5805del p.A1936Qfs*81 | Frame Shift Del (DEL) | VAF 36/338 reads (11%) | called by mutect2, varscan2
- PKHD1 | c.3688del p.V1230Yfs*11 | Frame Shift Del (DEL) | VAF 9/108 reads (8%) | called by mutect2, pindel
- RYR2 | c.2487del p.E830Kfs*3 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by pindel, varscan2
- STXBP5L | c.2787del p.W929* | Frame Shift Del (DEL) | VAF 19/124 reads (15%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- VWF | c.7571dup p.E2525Gfs*8 | Frame Shift Ins (INS) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- XPNPEP2 | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF546 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- ABCG4 | c.864G>T p.L288= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as COSV56645304; called by muse, varscan2
- ADGRG4 | c.8565A>T p.L2855= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as COSV54964215; called by muse, mutect2
- APOB | c.5955C>T p.T1985= | Silent (SNP) | VAF 10/161 reads (6%) | catalogued as COSV51948140; called by muse, mutect2
- BICD1 | c.499C>A p.R167= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV55683237, COSV55686034; called by muse, mutect2
- CD1B | c.549C>A p.T183= | Silent (SNP) | VAF 12/257 reads (5%) | catalogued as COSV63804998; called by muse, mutect2
- COL5A2 | c.3798A>T p.P1266= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV66413708; called by muse, mutect2
- DCAF12L2 | c.1290G>T p.A430= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV63581315, COSV63582525; called by muse, mutect2
- DNAJC12 | c.474A>G p.S158= | Silent (SNP) | VAF 64/820 reads (8%) | catalogued as COSV56549490; called by muse, mutect2
- DSCAML1 | c.5487G>T p.V1829= (on ENST00000321322; = p.V1769= on NM_020693.4) | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV100354836, COSV58400318; called by muse, mutect2
- EXTL3 | c.264G>T p.S88= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV55038660, COSV55039911; called by mutect2, varscan2
- FYB1 | c.1657A>C p.R553= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV60954024; called by muse, mutect2, varscan2
- HECW1 | c.3330A>G p.S1110= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs763694427, COSV67837711; called by muse, mutect2, varscan2
- HPSE2 | c.177C>T p.T59= | Silent (SNP) | VAF 26/356 reads (7%) | catalogued as rs762034031, COSV65198658; called by muse, mutect2
- IGHV3OR16-8 | c.255C>A p.G85= | Silent (SNP) | VAF 39/383 reads (10%) | called by muse, mutect2, varscan2
- KIF16B | c.3222G>T p.L1074= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV61712256; called by muse, mutect2
- LEP | c.69C>T p.P23= | Silent (SNP) | VAF 21/272 reads (8%) | catalogued as COSV58241575; called by muse, mutect2
- LILRB2 | c.75C>A p.T25= | Silent (SNP) | VAF 13/212 reads (6%) | catalogued as rs781041732, COSV58747706; called by muse, mutect2
- MEGF10 | c.1323C>G p.T441= | Silent (SNP) | VAF 16/245 reads (7%) | catalogued as COSV57254807; called by muse, mutect2
- MEGF10 | c.3363C>T p.S1121= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV57254829; called by mutect2, varscan2
- MFAP3L | c.1071A>T p.A357= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV64372833; called by muse, mutect2
- MKRN3 | c.864C>T p.A288= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs757533679, COSV58811631; called by muse, mutect2, varscan2
- MYBL1 | c.984G>A p.Q328= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV72919158; called by muse, mutect2, varscan2
- MYBL2 | c.1182C>T p.P394= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs761972194, COSV99406493; called by muse, mutect2
- NUP210L | c.600C>T p.P200= | Silent (SNP) | VAF 30/669 reads (4%) | catalogued as COSV55155231; called by muse, mutect2
- NXF3 | c.609G>T p.V203= | Silent (SNP) | VAF 18/225 reads (8%) | catalogued as COSV67704825; called by muse, mutect2
- OR1C1 | c.234C>A p.V78= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs755608030, COSV68716221; called by muse, mutect2, varscan2
- OR2L13 | c.453G>T p.G151= | Silent (SNP) | VAF 58/446 reads (13%) | catalogued as COSV63548593; called by muse, mutect2, varscan2
- OR5D18 | c.327G>A p.V109= | Silent (SNP) | VAF 14/392 reads (4%) | catalogued as rs1297217041, COSV61736728; called by muse, mutect2
- OR7G2 | c.783C>A p.T261= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV100560489; called by muse, mutect2
- OR8H3 | c.327T>C p.T109= | Silent (SNP) | VAF 28/682 reads (4%) | catalogued as COSV57910882; called by muse, mutect2
- PCDHA9 | c.1747C>A p.R583= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100969458; called by muse, mutect2
- PDZD8 | c.2271G>T p.L757= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV57827870; called by muse, mutect2, varscan2
- PHKA2 | c.105C>A p.A35= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV66055654; called by muse, mutect2
- PIGN | c.1497G>C p.L499= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV62951347; called by muse, mutect2
- PRDM9 | c.654C>G p.A218= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs559670911, COSV57011486; called by muse, mutect2, varscan2
- PRKAG3 | c.279C>T p.F93= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV52103365; called by muse, mutect2, varscan2
- PRR14L | c.5541C>A p.T1847= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100392534; called by muse, mutect2
- RHO | c.687C>A p.T229= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs143003934, COSV99960682; called by muse, mutect2
- RPGR | c.714G>T p.V238= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV58838956; called by muse, mutect2
- RYR2 | c.12030G>C p.V4010= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV63706667; called by muse, mutect2
- RYR3 | c.3112C>A p.R1038= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as COSV66800192, COSV66804814; called by muse, mutect2
- SI | c.4998C>A p.G1666= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100016638, COSV52295544; called by muse, mutect2, varscan2
- SYNE1 | c.6732T>G p.V2244= (on ENST00000367255 / NM_182961.4; = p.V2251= on NM_033071.3) | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV55070830; called by muse, mutect2
- TBC1D4 | c.615G>T p.L205= | Silent (SNP) | VAF 38/366 reads (10%) | catalogued as COSV66491098; called by muse, mutect2, varscan2
- TBX15 | c.492C>T p.D164= (on ENST00000369429 / NM_001330677.2; = p.D58= on NM_152380.3) | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV52874975; called by muse, mutect2
- TRPM1 | c.4533C>A p.V1511= | Silent (SNP) | VAF 35/510 reads (7%) | catalogued as COSV56640210; called by muse, mutect2
- ZNF366 | c.510G>T p.L170= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV100574423, COSV59218293; called by muse, mutect2, varscan2
- AL590867.2 | n.103G>T | RNA (SNP) | VAF 36/197 reads (18%) | catalogued as rs1236792225; called by muse, mutect2, varscan2
- SNORD116-21 | n.92C>G | RNA (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- UGT1A6 | c.862-23296T>C | Intron (SNP) | VAF 15/223 reads (7%) | catalogued as COSV100530420, COSV59396223, COSV59397972; called by muse, mutect2
- WDR43 | c.607-400G>T | Intron (SNP) | VAF 9/176 reads (5%) | catalogued as COSV99943054; called by muse, mutect2
